Somatic mutation profile of tumor specimen TCGA-IE-A3OV-01A (aliquot TCGA-IE-A3OV-01A-11D-A228-09) from TCGA case TCGA-IE-A3OV, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 42.7 years (15,607 days).
Specimen TCGA-IE-A3OV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa51f445-3df1-4b56-a613-2c77fd64fde2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IE-A3OV-11A (Solid Tissue Normal), aliquot TCGA-IE-A3OV-11A-22D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b18db7f-aaf3-4f78-ba5c-2d063af33be0

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 22, Silent 13, Frame Shift Del 2, Nonsense Mutation 1, Translation Start Site 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.3001A>C p.I1001L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV101201184; called by muse, mutect2, varscan2
- ACACB | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs149394526; called by muse, mutect2, varscan2
- BAIAP3 | c.881+1G>C p.X294_splice | Splice Site (SNP) | VAF 14/100 reads (14%) | catalogued as COSV100181658; called by muse, mutect2, varscan2
- CSMD1 | c.953A>T p.K318M | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101222026; called by muse, mutect2, varscan2
- FAM90A1 | c.635A>C p.Q212P | Missense Mutation (SNP) | VAF 54/267 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100274379; called by muse, mutect2, varscan2
- GALNT7 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); catalogued as COSV99397561; called by muse, mutect2, varscan2
- GK2 | c.589A>G p.T197A | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs968750874, COSV100725983; called by muse, mutect2, varscan2
- GLOD4 | c.776T>G p.I259S (on ENST00000301328 / NM_001366247.1; = p.I244S on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100022648; called by muse, mutect2, varscan2
- GPRC5B | c.1025A>T p.N342I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.499); catalogued as COSV56029194; called by muse, mutect2, varscan2
- KLHDC7B | c.1295C>T p.A432V (on ENST00000395676; = p.A1073V on NM_138433.5) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67464380; called by muse, mutect2, varscan2
- LATS2 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101231607; called by muse, mutect2
- MDM2 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99254687; called by muse, mutect2
- MDN1 | c.4687C>T p.R1563C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs761391000, COSV65522570; called by muse, mutect2, varscan2
- NAGPA | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | PolyPhen probably damaging (1); catalogued as rs772676182, COSV100392986, COSV56570546; called by muse, mutect2, varscan2
- NR6A1 | c.572C>A p.S191* (on ENST00000487099 / NM_033334.4; = p.S187* on NM_001489.5) | Nonsense Mutation (SNP) | VAF 3/34 reads (9%) | catalogued as COSV100748593; called by muse, mutect2
- NRXN1 | c.1211A>G p.D404G | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100455691; called by muse, mutect2, varscan2
- PCDHA13 | c.853G>T p.V285L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.155); catalogued as COSV99167036; called by muse, mutect2, varscan2
- PFKM | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs193298317, COSV99137008; called by muse, mutect2, varscan2
- SACS | c.7451G>T p.C2484F | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101207516, COSV66544774; called by muse, mutect2, varscan2
- SH3BP5 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53745833; called by muse, mutect2, varscan2
- SYT3 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100144184; called by muse, mutect2, varscan2
- TBXAS1 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV54942709, COSV99695563; called by muse, mutect2, varscan2
- TRIM31 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV65060027; called by muse, mutect2, varscan2
- TSSK2 | c.371T>G p.V124G | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV99351015; called by muse, mutect2, varscan2
- ZNF429 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV100641960; called by muse, mutect2, varscan2
- MYO18B | c.280del p.D94Tfs*27 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- TLR5 | c.518del p.K173Sfs*3 | Frame Shift Del (DEL) | VAF 11/30 reads (37%) | called by mutect2, pindel, varscan2
- ACOT12 | c.1650G>A p.G550= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs1197030823, COSV56899349; called by muse, mutect2, varscan2
- ARHGEF26 | c.1878G>A p.K626= | Silent (SNP) | VAF 38/102 reads (37%) | catalogued as COSV100726619; called by muse, mutect2, varscan2
- C1R | c.1584C>T p.N528= (on ENST00000536053 / NM_001354346.2; = p.N514= on NM_001733.7) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs762138868, COSV101605628; called by muse, mutect2, varscan2
- CNEP1R1 | c.213C>A p.T71= (on ENST00000427478 / NM_001281789.1; = p.T88= on NM_153261.5) | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV101208073; called by muse, mutect2
- DACT1 | c.1194G>A p.A398= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs111351020, COSV100241936; called by muse, mutect2, varscan2
- HR | c.1464G>T p.L488= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100455916; called by muse, mutect2, varscan2
- MDN1 | c.255A>G p.Q85= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs763060906, COSV101021516; called by muse, mutect2, varscan2
- MYO18B | c.156G>A p.A52= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs750611108, COSV59134697; called by muse, mutect2, varscan2
- NAAA | c.957G>A p.E319= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs761803860, COSV99715987; called by muse, mutect2, varscan2
- PHF24 | c.261C>T p.G87= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs780311819, COSV54273146; called by muse, mutect2, varscan2
- RFX6 | c.237C>T p.N79= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs749866506, COSV60589932; called by muse, mutect2
- TRIM44 | c.709T>C p.L237= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs767212429, COSV100195212; called by muse, mutect2, varscan2
- ZNF790 | c.1896C>T p.F632= | Silent (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100764854; called by muse, mutect2, varscan2
